Somatic mutation profile of tumor specimen 0E1NZZ from CCDI case PBCWMG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1NZZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdeb31ec-8cc6-42c4-a0dc-f49a8cfa6869.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1NYR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6095b7eb-fb0f-48aa-b1bc-da2e0f828c47

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KANSL1L | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 64/848 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759250532, COSV55992992; called by muse, mutect2
- FAM83C | c.236A>G p.D79G | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); called by muse, mutect2
